Surgical pathology report (de-identified scan), TCGA case TCGA-38-4631, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site UNC, specimen TCGA-38-4631-01A (Primary Tumor).

[page 1 of 2]
CLINICAL INFORMATION

The patient is with a reported history of non small cell carcinoma involving the left lung. No other clinical information is provided.

GROSS DESCRIPTIONS

Received are six formalin-filled containers labeled with the patient's name and medical record number. The first container is additionally labeled "station 9." It holds three nodules of tan/black, soft tissue which in aggregate measure 2.1 x 0.7 x 0.6 cm. These are submitted in entirety in block 1.

The second container is additionally labeled "station 10." It holds a single somewhat irregularly shaped nodule of tan/black, soft tissue which measures 2.2 x 1.1 x 0.7 cm. The specimen is bisected and submitted in total in block 2.

The third container is appropriately labeled "station 7." It holds two nodules of tan, soft tissue using focal areas of black discoloration. The larger fragment measures 2.9 x 1.3 x 0.9 cm, and the smaller fragment measures 1.8 x 0.6 x 0.5 cm. The specimens are bisected and half of the smaller fragment and half of the larger fragment are submitted in block 3, and the remaining half of each specimen are submitted in block 4.

The next container is appropriately labeled "station 5." It holds three irregular shaped fragments of tan, soft tissue with focal areas of black discoloration. In aggregate, these measure 3.2 x 2.2 x 1.2 cm maximally.

The specimen is submitted in its entirety in blocks 5 and 6.

The fifth container is additionally labeled "lymph node 4L." It holds two nodules of tan/brown, soft tissue. The smaller nodule measures 0.7 x 0.4 x 0.5 cm, and the larger measures 2.2 x 0.9 x 0.9 cm. Both are submitted in block 7.

The sixth container holds a left lung consisting of a left upper lobe as well as a left lower lobe and lingula. The apex of the left upper lobe has the pleural surface marked in black ink, and has previously been opened for tissue procurement revealing a tan/white lesion with central necrosis. The borders of this lesion are somewhat irregular. This mass measures 4.6 cm x 4.2 cm x 4.3 cm. This lesion appears to come within half of a mm of the pleural surface. This lesion does not appear intimately associated with any airways grossly. The remaining lung parenchyma appears tan/brown in color with focal enlargement of air spaces.

Representative sections of the lesion and lung are submitted as per block summary. Several lymph nodes are present adjacent to the left upper lobe bronchus. They measure 1.5 and 1.2 and 1.1 cm in diameter, respectively. These are bisected and submitted in total in blocks 9 and 10.

Specimen fixation: formalin

Type of specimen/parts of lung received: left lung, including both upper and lower lobes

Size of specimen: 23.3 x 14.1 x 6.2 cm

Weight of specimen: 750 gm

Other attached structures: none

Tumor location: apex of left upper lobe, near periphery

Tumor size: 4.6 x 4.2 x 4.3 cm

Relationship of tumor to bronchus: not obviously associated

Distance of tumor to bronchial margin: 5.8 cm

Relationship/distance of tumor to pleura: grossly extends extremely close, 0.05 cm

Presence/absence of satellite tumor nodules: none

Involvement of attached structures by tumor: not identified

Description of nontumorous lung: focal dilatation of air spaces

BLOCK SUMMARY

- 1 - station 9 lymph nodes
- 2 - station 10 lymph nodes
- 3,4 - station 7 lymph nodes
- 5,6 - station 5 lymph nodes
- 7 - station 4L lymph nodes
- 8 - left upper lobe bronchial margin
- 9,10 - peribronchial lymph nodes (3)
- 11-15 - representative sections of tumor
- 16,17 - left upper lobe, lung parenchyma
- 18,19 - left lower lobe, lung parenchyma

LIGHT MICROSCOPY

Light microscopic examination is performed by Dr.

Tumor histologic type (WHO classification): adenocarcinoma

Tumor histologic grade (WHO classification): poorly differentiated

Tumor size (greatest dimension): 4.6 cm by gross measurement

Histologic assessment of surgical margins: negative

[page 2 of 2]
Pleural involvement: tumor focally extends to pleura but does not appear to penetrate it. In the area of closest approach of tumor to pleura, there is adherent adipose and skeletal muscle, consistent with focal adhesion to chest wall.

In-situ carcinoma: not identified

Invasion: angiolymphatic - present, vascular involvement within tumor mass perineural - not identified

Lymph nodes (by node group): below

Findings in nontumorous lung: emphysema, scattered lymphoid aggregates

SPECIAL STAINS

PAS stains show occasional intracytoplasmic globules which are diastase resistant.

DIAGNOSIS

LEFT LUNG, REMOVAL - POORLY DIFFERENTIATED ADENOCARCINOMA, 4.6 CM GREATEST DIMENSION

- VASCULAR SPACE INVASION IDENTIFIED WITHIN MAIN TUMOR MASS

- TUMOR EXTENDS TO, BUT NOT THROUGH, PLEURA

- SURGICAL MARGINS NEGATIVE FOR TUMOR

- 3 STATION 12 L LYMPH NODES WITH NO TUMOR SEEN (0/3)

LYMPH NODES, STATION 9, REMOVAL - NO TUMOR SEEN IN 4 LYMPH NODES (0/4)

LYMPH NODES, STATION 10, REMOVAL - NO TUMOR SEEN IN 2 LYMPH NODES (0/2)

LYMPH NODES, STATION 7, REMOVAL - NO TUMOR SEEN IN 2 LYMPH NODES (0/2)

LYMPH NODES, STATION 5, REMOVAL - NO TUMOR SEEN IN 3 LYMPH NODES (0/3)

LYMPH NODES, STATION 4L, REMOVAL - NO TUMOR SEEN IN 2 LYMPH NODES (0/2)

Source: NCI Genomic Data Commons file 8aa38933-8f8c-46cc-a7da-51a108056eb3 (TCGA-38-4631.FE8CEDAF-E5D1-4836-B6D7-6F21E5E8CD53.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).